Somatic mutation profile of tumor specimen ALCH-ADUH-TTP1-A (aliquot ALCH-ADUH-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADUH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 42.1 years (15,366 days).
Specimen ALCH-ADUH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cfe35e2-50a1-4a83-926f-d6b0968e49d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADUH-NB1-A (Blood Derived Normal), aliquot ALCH-ADUH-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/941e2526-cb1b-45d8-b16e-ad6f157abd1d

The open-access MAF lists 277 somatic variants for this specimen: 179 protein-altering or splice-affecting, 67 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 67, Nonsense Mutation 16, Intron 11, RNA 8, Splice Region 6, 3'UTR 6, Splice Site 5, 5'UTR 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ENG | c.817-1G>C p.X273_splice | Splice Site (SNP) | VAF 13/107 reads (12%) | catalogued as rs1564455715, CS147623, CS159707; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 148/1213 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs1057520005, COSV52707923, COSV52708386, COSV52728497, COSV53727597; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS18 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 23/512 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV51418764; called by muse, mutect2
- ADH1B | c.1112C>G p.T371S | Missense Mutation (SNP) | VAF 28/403 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV100520829, COSV59295344; called by muse, mutect2
- AK7 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 23/802 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1440183059, COSV50882891; called by muse, mutect2
- ALAS2 | c.950C>G p.S317C | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); catalogued as rs1185780300; called by muse, mutect2, varscan2
- APOB | c.11033C>T p.P3678L | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51946433; called by muse, mutect2
- ASTN2 | c.2699A>G p.Y900C (on ENST00000313400 / NM_001365069.1; = p.Y849C on NM_014010.5) | Missense Mutation (SNP) | VAF 49/388 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs774699825, COSV57752385; called by muse, mutect2, varscan2
- ATF7IP2 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 10/318 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as rs1239555520, COSV61092456; called by muse, mutect2
- BEGAIN | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs1363257718; called by muse, mutect2
- BMPER | c.1196C>T p.S399L | Missense Mutation (SNP) | VAF 56/1104 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as rs1252694483, COSV51811898; called by muse, mutect2
- CAMTA1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.207); catalogued as rs866487669, COSV99079284; called by muse, mutect2
- CASZ1 | c.2816+8G>A | Splice Region (SNP) | VAF 11/227 reads (5%) | catalogued as rs1184543145; called by muse, mutect2
- CDHR1 | c.1101G>A p.M367I | Missense Mutation (SNP) | VAF 30/510 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as rs750245106; called by muse, mutect2
- CHST1 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs748972829, COSV57325854; called by muse, mutect2
- CNTN1 | c.1765G>C p.V589L | Missense Mutation (SNP) | VAF 32/664 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV61646020; called by muse, mutect2
- COL13A1 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 11/197 reads (6%) | catalogued as COSV62568600; called by muse, mutect2
- CXXC5 | c.815G>C p.R272P | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100210710; called by muse, mutect2, varscan2
- DDX53 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV60069104; called by muse, mutect2, varscan2
- DNAH12 | c.7849C>G p.L2617V (on ENST00000351747; = p.L3485V on NM_001366028.2) | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.895); catalogued as COSV100696289; called by muse, mutect2
- ENGASE | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1214479093; called by muse, mutect2
- F9 | c.575C>A p.A192D | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as CD045832; called by muse, mutect2, varscan2
- GALNT17 | c.1124G>T p.R375L | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV61149949, COSV61154773; called by muse, mutect2, varscan2
- GALR1 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 29/721 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55319825; called by muse, mutect2
- GSE1 | c.3518C>A p.A1173E | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV53672538; called by muse, mutect2, varscan2
- HAS1 | c.1223C>G p.S408C | Missense Mutation (SNP) | VAF 74/786 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV55787638, COSV55788774; called by muse, mutect2
- HM13 | c.799G>C p.V267L | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59437482; called by muse, mutect2
- HRC | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs775263588, COSV53259136; called by muse, mutect2, varscan2
- HTR3D | c.789C>A p.F263L (on ENST00000382489 / NM_001163646.2; = p.F90L on NM_182537.3) | Missense Mutation (SNP) | VAF 58/712 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61914004; called by muse, mutect2
- IL1RAPL1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV100150966; called by muse, mutect2
- ILK | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 44/904 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54449542; called by muse, mutect2
- KCNU1 | c.3272C>G p.S1091C | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV67759597; called by muse, mutect2, varscan2
- KRTAP16-1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753221510; called by muse, mutect2
- LRP1B | c.11086G>A p.E3696K | Missense Mutation (SNP) | VAF 27/358 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1364597921; called by muse, mutect2
- LRRC37B | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 36/452 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1257311975; called by muse, mutect2
- LRRK2 | c.3972G>C p.Q1324H | Missense Mutation (SNP) | VAF 15/405 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.712); catalogued as COSV100111404; called by muse, mutect2
- MAST4 | c.4096G>A p.G1366R (on ENST00000403625 / NM_001164664.2; = p.G1177R on NM_015183.3) | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368420355; called by muse, mutect2
- MYBPC2 | c.2332G>C p.E778Q | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV63094520; called by muse, mutect2, varscan2
- MYORG | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs753048179; called by muse, mutect2, varscan2
- NOS1AP | c.450G>T p.K150N | Missense Mutation (SNP) | VAF 34/748 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62633428; called by muse, mutect2
- OCM2 | c.266C>G p.A89G | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV57535131; called by muse, mutect2, varscan2
- OR51A2 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 30/792 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as rs1265566924; called by muse, mutect2
- PASD1 | c.862C>G p.R288G | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV64854796; called by muse, mutect2
- PCDH15 | c.1959G>C p.E653D | Missense Mutation (SNP) | VAF 20/556 reads (4%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.602); catalogued as COSV57326797; called by muse, mutect2
- PHEX | c.1918C>A p.L640M | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756017274; called by muse, mutect2, varscan2
- REC8 | c.175G>T p.G59C | Missense Mutation (SNP) | VAF 29/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1475840583; called by muse, mutect2
- RHOB | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 18/471 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV55357168; called by muse, mutect2
- ROBO3 | c.3976T>G p.Y1326D | Missense Mutation (SNP) | VAF 39/292 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as COSV100127517; called by muse, mutect2, varscan2
- RPL5 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 38/542 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1198185864; called by muse, mutect2
- SH2D7 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 17/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60926618; called by muse, mutect2
- SLC5A2 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 29/515 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57890801; called by muse, mutect2
- SMARCA2 | c.4573G>A p.E1525K | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs775935502; called by muse, mutect2
- ST18 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV52504305; called by muse, mutect2
- ST8SIA4 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 36/720 reads (5%) | PolyPhen benign (0); catalogued as COSV51514339; called by muse, mutect2
- STUB1 | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.465); catalogued as COSV99555652; called by muse, mutect2
- TAGAP | c.2068G>C p.E690Q | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV57852851; called by muse, mutect2
- TRHDE | c.2975C>G p.S992C | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53838690; called by muse, mutect2
- TTN | c.9520G>A p.D3174N (on ENST00000591111; = p.D3128N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/608 reads (3%) | PolyPhen probably damaging (0.966); catalogued as rs984157404, COSV59957427; ClinVar: uncertain significance; called by muse, mutect2
- ZNF181 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 78/430 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.916); catalogued as rs749264826; called by muse, mutect2, varscan2
- ZNF461 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 218/591 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV64453619; called by muse, mutect2, varscan2
- ZNF484 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1034720549; called by muse, mutect2
- ZNF536 | c.2011C>G p.R671G | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62818669; called by muse, mutect2
- ABCD1 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACE | c.296A>T p.Q99L | Missense Mutation (SNP) | VAF 130/686 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1961C>A p.S654* | Nonsense Mutation (SNP) | VAF 111/783 reads (14%) | called by muse, mutect2, varscan2
- AGPS | c.261G>T p.R87= | Splice Region (SNP) | VAF 25/303 reads (8%) | called by muse, mutect2
- ANO5 | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 21/511 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2
- APOBEC3H | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARL5C | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2
- BBX | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- BPIFA3 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 30/601 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.062); called by muse, mutect2
- CCDC178 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- CCDC54 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 32/422 reads (8%) | called by muse, mutect2
- CD163L1 | c.3928T>A p.L1310M | Missense Mutation (SNP) | VAF 86/1000 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHAF1A | c.1819G>C p.E607Q | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CHST9 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2
- CHSY1 | c.71C>G p.S24W | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2
- CLCNKA | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 54/757 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- CLTRN | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- CNOT11 | c.1526C>G p.S509* | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | called by muse, mutect2
- COL4A4 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 25/582 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CORIN | c.1291A>C p.N431H | Missense Mutation (SNP) | VAF 33/414 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.161); called by muse, mutect2
- CPA4 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2
- CPB1 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 28/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CPT1A | c.1089G>T p.M363I | Missense Mutation (SNP) | VAF 27/492 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- CTNND1 | c.2014C>G p.L672V (on ENST00000399050 / NM_001085458.2; = p.L666V on NM_001331.3) | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- CUBN | c.5701G>C p.E1901Q | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.124); called by muse, mutect2
- CYB5R4 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 27/252 reads (11%) | called by muse, mutect2, varscan2
- DLL1 | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 93/1084 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2
- DMXL1 | c.5215G>C p.A1739P | Missense Mutation (SNP) | VAF 69/549 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH2 | c.6128A>G p.K2043R | Missense Mutation (SNP) | VAF 50/283 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- DOCK3 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2
- EGFL6 | c.469C>A p.L157M | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2
- EPHA7 | c.676T>G p.S226A | Missense Mutation (SNP) | VAF 46/428 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- FAM47A | c.748G>T p.G250W | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- FBF1 | c.628G>A p.D210N (on ENST00000586717; = p.D224N on NM_001319193.1) | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); called by muse, mutect2
- FES | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 45/648 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.238); called by muse, mutect2
- GNA11 | c.725C>A p.S242* | Nonsense Mutation (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- GOLGA6L2 | c.2239G>T p.G747* | Nonsense Mutation (SNP) | VAF 73/658 reads (11%) | called by muse, mutect2, varscan2
- GOLIM4 | c.521C>T p.T174I | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- GRM5 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 65/570 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- HECW1 | c.3323A>T p.H1108L | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2
- ITGAV | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KATNIP | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 36/528 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- KMT2D | c.16531G>C p.D5511H | Missense Mutation (SNP) | VAF 22/563 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAMA2 | c.4651G>A p.G1551R | Missense Mutation (SNP) | VAF 65/558 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LONRF1 | c.2206G>T p.V736F | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP1 | c.5158G>A p.D1720N | Missense Mutation (SNP) | VAF 29/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- LRRC7 | c.1373G>A p.R458K (on ENST00000651989 / NM_001370785.2; = p.R425K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0.228); called by muse, mutect2
- LTBP3 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 58/860 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MAN2B1 | c.2049A>G p.T683= | Splice Region (SNP) | VAF 59/594 reads (10%) | called by muse, mutect2, varscan2
- MAP3K1 | c.3340A>G p.T1114A | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- MAPRE1 | c.562A>C p.N188H | Missense Mutation (SNP) | VAF 52/520 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MATR3 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 27/879 reads (3%) | called by muse, mutect2
- MFN1 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2
- MFN2 | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 38/693 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- MMP16 | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYH6 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 25/651 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- NEURL3 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 17/329 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.247); called by muse, mutect2
- NSD1 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.078); called by muse, mutect2
- NSMAF | c.2505G>C p.Q835H | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2
- NTRK3 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 30/924 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.029); called by muse, mutect2
- NUP98 | c.5363G>T p.G1788V (on ENST00000359171 / NM_001365126.1; = p.G1771V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/926 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.738); called by muse, mutect2
- OPRL1 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 62/702 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR13C4 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- OR2M2 | c.545C>A p.P182H | Missense Mutation (SNP) | VAF 19/424 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR3A1 | c.136C>T p.L46F | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- OTOG | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 26/395 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.237); called by muse, mutect2
- PIGL | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PIK3CG | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 14/505 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.022); called by muse, mutect2
- POMT2 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 37/602 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- PPFIA1 | c.1333A>G p.K445E | Missense Mutation (SNP) | VAF 51/328 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- PRTFDC1 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2
- PYHIN1 | c.580-1G>C p.X194_splice | Splice Site (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2
- RAI1 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- RESF1 | c.2551A>C p.T851P | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2
- RIMS2 | c.2822G>T p.R941L (on ENST00000666250 / NM_001348490.2; = p.R749L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/387 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPL10 | c.493-1G>C p.X165_splice | Splice Site (SNP) | VAF 110/900 reads (12%) | called by muse, mutect2, varscan2
- SCARF1 | c.1398G>T p.M466I | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, varscan2
- SELENON | c.885G>C p.E295D | Missense Mutation (SNP) | VAF 38/644 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SFXN4 | c.585G>C p.W195C | Missense Mutation (SNP) | VAF 33/776 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.248); called by muse, mutect2
- SGCA | c.721C>A p.R241S | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.1); called by muse, mutect2
- SHCBP1 | c.1402G>T p.G468* | Nonsense Mutation (SNP) | VAF 24/331 reads (7%) | called by muse, mutect2
- SI | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 19/436 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- SIMC1 | c.2527G>A p.D843N (on ENST00000443967 / NM_001308196.1; = p.D428N on NM_198567.5) | Missense Mutation (SNP) | VAF 44/480 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2
- SLC18A2 | c.-15-3C>A | Splice Region (SNP) | VAF 23/359 reads (6%) | called by muse, mutect2
- SLC26A9 | c.1118G>C p.G373A | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC39A4 | c.1138C>G p.L380V (on ENST00000301305 / NM_001374839.1; = p.L355V on NM_017767.3) | Missense Mutation (SNP) | VAF 37/513 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC3A2 | c.641C>A p.P214Q | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC6A11 | c.1399G>C p.D467H | Missense Mutation (SNP) | VAF 42/496 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMG9 | c.206C>G p.S69* | Nonsense Mutation (SNP) | VAF 35/320 reads (11%) | called by muse, mutect2, varscan2
- SNX13 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 32/678 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.548); called by muse, mutect2
- SOX6 | c.764A>T p.Q255L | Missense Mutation (SNP) | VAF 24/593 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2
- SRBD1 | c.1764C>T p.F588= | Splice Region (SNP) | VAF 15/225 reads (7%) | called by muse, mutect2
- SRGAP1 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 17/245 reads (7%) | called by muse, mutect2
- SS18 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- STYXL2 | c.971T>A p.L324Q | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); called by muse, mutect2
- TGM5 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.676); called by muse, mutect2
- TMEFF2 | c.731G>C p.R244T | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.205); called by muse, mutect2
- TMEM209 | c.420G>C p.L140F | Missense Mutation (SNP) | VAF 22/578 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- TNXB | c.8470G>A p.V2824M (on ENST00000647633; = p.V2577M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TRAPPC12 | c.1604-2A>T p.X535_splice | Splice Site (SNP) | VAF 32/590 reads (5%) | called by muse, mutect2
- TRHR | c.217A>T p.M73L | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.01); called by muse, mutect2
- TRIM8 | c.183G>C p.Q61H | Missense Mutation (SNP) | VAF 66/1028 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRPM1 | c.3015G>T p.M1005I | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2
- TTL | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 44/572 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.742); called by muse, mutect2
- TUBD1 | c.717C>G p.F239L | Missense Mutation (SNP) | VAF 52/488 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TUBGCP2 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 19/327 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TYRO3 | c.125-1G>T p.X42_splice | Splice Site (SNP) | VAF 64/811 reads (8%) | called by muse, mutect2
- UBASH3A | c.1485A>G p.E495= | Splice Region (SNP) | VAF 16/516 reads (3%) | called by muse, mutect2
- UBXN2B | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 17/346 reads (5%) | called by muse, mutect2
- UGDH | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 63/725 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2
- USP11 | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2
- WNT3 | c.813G>C p.E271D | Missense Mutation (SNP) | VAF 38/492 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.031); called by muse, mutect2
- YLPM1 | c.3973G>A p.E1325K | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZFHX4 | c.2353C>G p.H785D | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF461 | c.1057G>T p.G353* | Nonsense Mutation (SNP) | VAF 223/595 reads (37%) | called by muse, mutect2, varscan2
- ZNF747 | c.200G>C p.R67P | Missense Mutation (SNP) | VAF 33/403 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- ZPLD1 | c.218G>T p.R73M (on ENST00000466937 / NM_001329788.1; = p.R89M on NM_175056.2) | Missense Mutation (SNP) | VAF 37/587 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2
- ACTB | c.201G>A p.L67= | Silent (SNP) | VAF 36/894 reads (4%) | called by muse, mutect2
- ANKRD36B | c.567C>G p.L189= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- ARFGEF3 | c.4383G>C p.L1461= | Silent (SNP) | VAF 10/250 reads (4%) | called by muse, mutect2
- ARNT2 | c.1848C>G p.L616= | Silent (SNP) | VAF 30/600 reads (5%) | called by muse, mutect2
- ATP13A3 | c.420C>T p.F140= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- CACNA1C | c.708G>A p.L236= | Silent (SNP) | VAF 16/182 reads (9%) | catalogued as COSV59756473; called by muse, mutect2
- CDC7 | c.1423T>C p.L475= | Silent (SNP) | VAF 21/382 reads (5%) | called by muse, mutect2
- CDHR4 | c.2364C>T p.L788= | Silent (SNP) | VAF 24/231 reads (10%) | called by muse, mutect2
- CFAP91 | c.1779G>A p.E593= | Silent (SNP) | VAF 19/353 reads (5%) | called by muse, mutect2
- COL12A1 | c.144A>G p.P48= | Silent (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2, varscan2
- CPN1 | c.592C>A p.R198= | Silent (SNP) | VAF 24/313 reads (8%) | called by muse, mutect2
- DDB1 | c.2151C>T p.L717= | Silent (SNP) | VAF 40/548 reads (7%) | catalogued as rs760992062; called by muse, mutect2
- DDX60 | c.5022C>T p.L1674= | Silent (SNP) | VAF 26/201 reads (13%) | called by muse, mutect2, varscan2
- DIAPH1 | c.1374G>A p.Q458= | Silent (SNP) | VAF 48/516 reads (9%) | called by muse, mutect2
- EIF2B5 | c.2189G>A p.*730= (on ENST00000647909; = p.*722= on NM_003907.3) | Silent (SNP) | VAF 32/770 reads (4%) | catalogued as rs1428018974; called by muse, mutect2
- EXOC6B | c.606C>G p.L202= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- FAM83C | c.771C>T p.L257= | Silent (SNP) | VAF 32/516 reads (6%) | catalogued as COSV65582713; called by muse, mutect2
- FANCF | c.258C>T p.L86= | Silent (SNP) | VAF 60/1218 reads (5%) | catalogued as rs146352365, COSV59416996; called by muse, mutect2
- FEM1C | c.459G>A p.L153= | Silent (SNP) | VAF 18/575 reads (3%) | called by muse, mutect2
- FREM3 | c.4335C>A p.T1445= | Silent (SNP) | VAF 16/488 reads (3%) | called by muse, mutect2
- GABRG1 | c.88C>T p.L30= | Silent (SNP) | VAF 23/427 reads (5%) | catalogued as COSV54949394; called by muse, mutect2
- GOLGA1 | c.462G>A p.Q154= | Silent (SNP) | VAF 39/289 reads (13%) | catalogued as rs1234778789; called by muse, mutect2, varscan2
- HERC2 | c.7878A>G p.E2626= | Silent (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- HOXA9 | c.6C>A p.A2= | Silent (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- IGHG1 | c.357G>T p.G119= | Silent (SNP) | VAF 17/386 reads (4%) | catalogued as rs368947240; called by muse, mutect2
- IGKV1D-8 | c.60C>A p.A20= | Silent (SNP) | VAF 16/273 reads (6%) | called by muse, mutect2
- ITIH4 | c.816C>G p.P272= | Silent (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- KRT75 | c.1404T>C p.S468= | Silent (SNP) | VAF 22/729 reads (3%) | called by muse, mutect2
- KRT78 | c.717G>C p.L239= | Silent (SNP) | VAF 28/537 reads (5%) | catalogued as COSV58850916; called by muse, mutect2
- MED12L | c.2358G>T p.V786= | Silent (SNP) | VAF 33/400 reads (8%) | called by muse, mutect2
- MROH6 | c.1392G>C p.L464= | Silent (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- MUC5AC | c.16620C>T p.I5540= | Silent (SNP) | VAF 33/627 reads (5%) | called by muse, mutect2
- NAPSA | c.1134G>A p.L378= | Silent (SNP) | VAF 91/498 reads (18%) | called by muse, mutect2, varscan2
- NME9 | c.687C>T p.L229= (on ENST00000333911 / NM_001349024.2; = p.L168= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/536 reads (9%) | called by muse, mutect2
- OPRK1 | c.942C>T p.F314= | Silent (SNP) | VAF 35/847 reads (4%) | called by muse, mutect2
- OR10Q1 | c.81C>T p.F27= | Silent (SNP) | VAF 23/432 reads (5%) | catalogued as rs1167398219; called by muse, mutect2
- OR56A4 | c.258C>T p.L86= | Silent (SNP) | VAF 14/247 reads (6%) | catalogued as COSV58109858; called by muse, mutect2
- PCDHGB2 | c.1626C>G p.L542= | Silent (SNP) | VAF 30/806 reads (4%) | called by muse, mutect2
- PDZD2 | c.7455G>A p.L2485= | Silent (SNP) | VAF 29/509 reads (6%) | catalogued as COSV56854914; called by muse, mutect2
- PIGG | c.1290C>T p.Y430= | Silent (SNP) | VAF 64/559 reads (11%) | catalogued as rs764654528; called by muse, mutect2, varscan2
- PKN1 | c.225G>A p.L75= | Silent (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- PSME4 | c.78C>T p.F26= | Silent (SNP) | VAF 23/290 reads (8%) | catalogued as COSV66364404; called by muse, mutect2
- RAB3GAP1 | c.2940C>T p.F980= | Silent (SNP) | VAF 37/1045 reads (4%) | called by muse, mutect2
- RHAG | c.21C>A p.L7= | Silent (SNP) | VAF 77/583 reads (13%) | called by muse, mutect2, varscan2
- RNF167 | c.234C>G p.V78= | Silent (SNP) | VAF 11/312 reads (4%) | called by muse, mutect2
- RYR1 | c.13848C>A p.A4616= | Silent (SNP) | VAF 210/689 reads (30%) | catalogued as COSV62099647; called by muse, mutect2, varscan2
- SERINC5 | c.1146G>A p.E382= | Silent (SNP) | VAF 16/292 reads (5%) | catalogued as COSV72596485; called by muse, mutect2
- SIPA1L3 | c.1863G>A p.R621= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- SKI | c.1857C>G p.L619= | Silent (SNP) | VAF 56/785 reads (7%) | called by muse, mutect2
- SLC22A3 | c.324C>G p.L108= | Silent (SNP) | VAF 53/620 reads (9%) | catalogued as rs766552536; called by muse, mutect2
- SMG1 | c.1926G>A p.L642= | Silent (SNP) | VAF 12/337 reads (4%) | called by muse, mutect2
- STUB1 | c.87C>G p.L29= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- TAF6L | c.1803C>T p.I601= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as rs1214088366; called by muse, mutect2
- TBX1 | c.315G>A p.A105= | Silent (SNP) | VAF 43/813 reads (5%) | catalogued as COSV60352651; called by muse, mutect2
- TMEM25 | c.1041C>T p.L347= | Silent (SNP) | VAF 17/328 reads (5%) | called by muse, mutect2
- TOR3A | c.918C>G p.L306= | Silent (SNP) | VAF 14/224 reads (6%) | catalogued as COSV61680526; called by muse, mutect2
- TRPM6 | c.5004C>T p.L1668= | Silent (SNP) | VAF 37/790 reads (5%) | catalogued as COSV62510184; called by muse, mutect2
- TTC28 | c.720G>T p.L240= | Silent (SNP) | VAF 29/396 reads (7%) | called by muse, mutect2
- TTL | c.21C>T p.R7= | Silent (SNP) | VAF 46/580 reads (8%) | catalogued as rs752655545; called by muse, mutect2
- URGCP | c.1224G>A p.L408= (on ENST00000453200 / NM_001077663.3; = p.L399= on NM_017920.4) | Silent (SNP) | VAF 23/478 reads (5%) | called by muse, mutect2
- USH2A | c.9939G>C p.V3313= | Silent (SNP) | VAF 45/735 reads (6%) | called by muse, mutect2
- VANGL1 | c.264C>T p.S88= | Silent (SNP) | VAF 26/474 reads (5%) | called by muse, mutect2
- XPNPEP1 | c.954C>G p.L318= | Silent (SNP) | VAF 46/668 reads (7%) | called by muse, mutect2
- XRCC3 | c.993G>A p.T331= | Silent (SNP) | VAF 29/482 reads (6%) | catalogued as rs765078097; called by muse, mutect2
- ZDHHC5 | c.1902G>A p.S634= | Silent (SNP) | VAF 9/140 reads (6%) | catalogued as rs1455474706, COSV54707170; called by muse, mutect2
- ZFP62 | c.2178G>A p.E726= (on ENST00000502412 / NM_001377944.1; = p.E693= on NM_152283.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 25/278 reads (9%) | called by muse, mutect2
- ZNF534 | c.87G>A p.Q29= | Silent (SNP) | VAF 17/496 reads (3%) | called by muse, mutect2
- AC068058.1 | n.114C>G | RNA (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- ADAM15 | c.80-162C>G | Intron (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- AP001267.5 | c.-799+5276G>A | Intron (SNP) | VAF 47/666 reads (7%) | catalogued as COSV100329289; called by muse, mutect2
- ARHGEF16 | c.1305+16G>C | Intron (SNP) | VAF 13/266 reads (5%) | called by muse, mutect2
- C9orf62 | n.171G>A | RNA (SNP) | VAF 15/305 reads (5%) | called by muse, mutect2
- CAPN5 | c.-36+6039C>A | Intron (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- CCDC88B | c.2617-328G>T | Intron (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- CHRND | c.*989G>C | 3'UTR (SNP) | VAF 54/1145 reads (5%) | called by muse, mutect2
- DCHS2 | n.1655G>A | RNA (SNP) | VAF 34/334 reads (10%) | called by muse, mutect2
- EHMT1 | c.3258+17G>C | Intron (SNP) | VAF 110/813 reads (14%) | called by muse, mutect2, varscan2
- FAM86B3P | n.712G>C | RNA (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- HOXA10 | c.*212C>T | 3'UTR (SNP) | VAF 192/1544 reads (12%) | called by muse, mutect2, varscan2
- HSP90B3P | n.1029G>C | RNA (SNP) | VAF 30/459 reads (7%) | called by muse, mutect2
- KIF19 | c.-23G>C | 5'UTR (SNP) | VAF 13/203 reads (6%) | catalogued as COSV100739067; called by muse, mutect2
- KRT87P | n.913G>A | RNA (SNP) | VAF 32/354 reads (9%) | catalogued as rs1283888284; called by muse, mutect2
- LGSN | c.163+1137C>T | Intron (SNP) | VAF 12/246 reads (5%) | catalogued as rs1027857288; called by muse, mutect2
- LHX6 | chr9:122228367 C>T | 5'Flank (SNP) | VAF 26/289 reads (9%) | called by muse, mutect2
- MAFF | c.*35C>T | 3'UTR (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- MED13L | c.5589-19C>T | Intron (SNP) | VAF 18/590 reads (3%) | catalogued as rs892701793; called by muse, mutect2
- MOCS1 | c.*1120G>C | 3'UTR (SNP) | VAF 54/916 reads (6%) | called by muse, mutect2
- MPZ | c.585-12C>T | Intron (SNP) | VAF 62/1083 reads (6%) | catalogued as rs375616364; called by muse, mutect2
- MSL3P1 | n.458G>A | RNA (SNP) | VAF 68/990 reads (7%) | called by muse, mutect2
- NFYC | c.388-750G>A | Intron (SNP) | VAF 14/182 reads (8%) | called by muse, mutect2
- NXT2 | chrX:109535926 G>C | 5'Flank (SNP) | VAF 21/232 reads (9%) | called by muse, mutect2
- RP1 | c.-5C>G | 5'UTR (SNP) | VAF 32/728 reads (4%) | called by muse, mutect2
- SCN4B | c.*2285C>T | 3'UTR (SNP) | VAF 56/920 reads (6%) | called by muse, mutect2
- SYCE1 | chr10:133568017 G>T | 5'Flank (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- TRAPPC4 | c.-1G>C | 5'UTR (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2
- TRIM52 | c.814-9A>G | Intron (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- VAPB | c.*1286G>C | 3'UTR (SNP) | VAF 28/524 reads (5%) | catalogued as rs1266795904; called by muse, mutect2
- ZNF971P | n.965T>G | RNA (SNP) | VAF 24/557 reads (4%) | called by muse, mutect2
